Gene-level copy-number profile of tumor specimen C3N-01337-04 from CPTAC case C3N-01337, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 52.9 years (19,312 days).
Specimen C3N-01337-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c016116b-c6c4-425d-84c5-c9128d768993.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01337-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/9acb912d-ff91-4202-abbc-9a0802382bf7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 634; copy number 1: 12,667; copy number 2: 39,524; copy number 3: 5,994; copy number 4: 65; copy number 7: 27.

Homozygous deletions (total copy number 0; autosomes only): 121 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,906,196–248,937,043, 3 genes: PGBD2, RNU6-1205P, RPL23AP25.
- chr3:11,745–3,057,959, 25 genes (within-gene range 0–2): LINC01986, AC066595.1, CHL1-AS2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144, CNTN4, CNTN4-AS2, AC087427.1, HINT2P1, DNAJC19P4.
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–2): RN7SL5P.
- chr9:61,190,003–61,453,030, 7 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:61,615,835–61,642,494, 2 genes: FAM242D, Y_RNA.
- chr9:94,900,429–94,904,754, 1 gene (within-gene range 0–3): AL807757.2.
- chr14:106,874,583–106,879,812, 2 genes: IGHV7-81, IGHVIII-82.
- chr16:34,941,977–35,912,516, 80 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:10,654,261–11,326,996, 27 genes, copy number 7 (within-gene range 3–7): ILF3, QTRT1, DNM2, MIR638, MIR4748, MIR199A1, MIR6793, TMED1, C19orf38, HIKESHIP2, CARM1, YIPF2, TIMM29, SMARCA4, AC011442.1, RN7SL192P, AC006127.1, LDLR, MIR6886, SPC24, KANK2, DOCK6, AC011472.1, AC011472.5, AC011472.4, ANGPTL8, TSPAN16.

Autosomal genes at a single copy (total copy number 1): 10,325. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
